Somatic mutation profile of tumor specimen TCGA-CC-A7IF-01A (aliquot TCGA-CC-A7IF-01A-11D-A33K-10) from TCGA case TCGA-CC-A7IF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 59.8 years (21,845 days).
Specimen TCGA-CC-A7IF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 348da9ac-ac4e-45a9-9133-5f41d97624cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A7IF-10A (Blood Derived Normal), aliquot TCGA-CC-A7IF-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/119ac78b-bf8d-42ac-ac3a-fe791745e51c

The open-access MAF lists 134 somatic variants for this specimen: 106 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 25, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 3, Intron 2, Frame Shift Ins 2, Splice Region 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM29 | c.2191C>A p.Q731K | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV63663863; called by muse, mutect2
- ADCY2 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs968274397, COSV57874000, COSV57900327; called by muse, mutect2, varscan2
- AQP11 | c.232A>T p.T78S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV57992516; called by muse, mutect2, varscan2
- ARAP1 | c.2509C>T p.Q837* (on ENST00000393609 / NM_001040118.2; = p.Q592* on NM_015242.4) | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as COSV61991965; called by muse, mutect2
- ARMCX1 | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100863152; called by muse, mutect2, varscan2
- ASTL | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.364); catalogued as COSV60904325; called by muse, mutect2, varscan2
- BAG5 | c.1238A>G p.D413G | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54571143; called by muse, mutect2, varscan2
- BCAT1 | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53911674; called by muse, mutect2, varscan2
- BPNT2 | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52907508; called by muse, mutect2, varscan2
- BTBD7 | c.1703G>A p.G568D | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1425545856, COSV58286223; called by muse, mutect2, varscan2
- BUD13 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV52768372; called by muse, mutect2, varscan2
- C20orf27 | c.97G>T p.D33Y (on ENST00000379772 / NM_001258429.2; = p.D58Y on NM_001039140.3) | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV53924010; called by muse, mutect2, varscan2
- CACNA2D1 | c.182A>T p.Y61F | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV62380126; called by muse, mutect2, varscan2
- CACNB1 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59998916; called by muse, mutect2, varscan2
- CALR | c.1240A>G p.K414E | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.492); catalogued as COSV57125854; called by muse, mutect2, varscan2
- CATSPERB | c.2746A>G p.T916A | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV56426933; called by muse, mutect2, varscan2
- CCDC93 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV60121448; called by muse, mutect2, varscan2
- CCSER2 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 70/158 reads (44%) | catalogued as COSV56505699; called by muse, mutect2, varscan2
- CCT5 | c.723A>C p.K241N | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54724113; called by muse, mutect2, varscan2
- CHPT1 | c.442T>G p.S148A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV57533503; called by muse, mutect2, varscan2
- CLCA1 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52328086; called by muse, mutect2
- COG3 | c.1655G>T p.G552V | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs551149553, COSV63072790; called by muse, mutect2, varscan2
- DIPK1B | c.159C>A p.Y53* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as COSV65462370; called by muse, mutect2, varscan2
- DNAH5 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs745647908, COSV54226941; called by muse, mutect2, varscan2
- DNAH8 | c.7876T>C p.C2626R | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs937388868, COSV59448315; called by muse, mutect2, varscan2
- DNAJA2 | c.361A>C p.K121Q | Missense Mutation (SNP) | VAF 150/213 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV57694817; called by muse, mutect2, varscan2
- DOCK10 | c.3109C>A p.H1037N | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs752115203, COSV51403760, COSV99288764; called by muse, mutect2, varscan2
- DYNC2H1 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV62094760, COSV62106828; called by muse, mutect2, varscan2
- DYRK4 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs545558326, COSV50539599, COSV50543842; called by muse, mutect2, varscan2
- EFHD2 | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV65658035; called by muse, mutect2, varscan2
- EMP2 | c.227G>T p.C76F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.489); catalogued as COSV63995963; called by muse, mutect2, varscan2
- EZHIP | c.1318C>A p.P440T | Missense Mutation (SNP) | VAF 55/68 reads (81%) | SIFT tolerated (0.8); PolyPhen benign (0.112); catalogued as COSV100539436, COSV57956359; called by muse, mutect2, varscan2
- FBXL18 | c.734A>T p.E245V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV66666835; called by muse, mutect2, varscan2
- FCRL4 | c.1410G>C p.Q470H | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.678); catalogued as COSV99619174, COSV99620435; called by muse, varscan2
- FREM1 | c.2640G>T p.E880D | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV66524089; called by muse, mutect2, varscan2
- GFI1B | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs764276098, COSV59745036; called by muse, mutect2, varscan2
- GIMAP1 | c.16A>C p.M6L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV56188257; called by muse, mutect2, varscan2
- GNE | c.260A>G p.N87S (on ENST00000396594 / NM_001128227.3; = p.N56S on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as COSV64951979; called by muse, mutect2, varscan2
- GPR119 | c.532A>T p.M178L | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52275722; called by muse, mutect2, varscan2
- GPR149 | c.959T>A p.V320D | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV67667461; called by muse, mutect2, varscan2
- GRXCR1 | c.159T>A p.D53E | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.121); catalogued as COSV67671861; called by muse, mutect2, varscan2
- HTR5A | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55282585, COSV55286142; called by muse, mutect2, varscan2
- ICE1 | c.3065G>C p.G1022A | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV56819574; called by muse, mutect2, varscan2
- ITGA11 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.935); catalogued as rs1287408712, COSV100241816, COSV59877950; called by muse, mutect2, varscan2
- KCNK10 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); catalogued as rs750667713, COSV56645158; called by muse, mutect2, varscan2
- KCNT1 | c.2902T>A p.Y968N (on ENST00000488444; = p.Y987N on NM_020822.3) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV53701839; called by muse, mutect2, varscan2
- KDM4C | c.1639G>C p.V547L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV67186795; called by muse, mutect2, varscan2
- KDR | c.2398G>C p.G800R | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55765839; called by muse, mutect2, varscan2
- KIR2DL3 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs199818198, COSV60898782; called by muse, varscan2
- LGI2 | c.1616T>C p.I539T | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.41); catalogued as rs150163590; called by muse, mutect2, varscan2
- MAN1A2 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62978589; called by muse, mutect2, varscan2
- MAP3K14 | c.295C>G p.R99G | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV60922931, COSV60923658; called by muse, mutect2, varscan2
- MEX3C | c.1817A>C p.H606P | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.756); catalogued as rs757446156, COSV68529923; called by muse, mutect2, varscan2
- MRPL13 | c.221A>G p.Q74R | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.416); catalogued as COSV60367584; called by muse, mutect2
- MSGN1 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs981143103, COSV55262966; called by muse, mutect2, varscan2
- MUC16 | c.27467C>A p.S9156Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as COSV67468410; called by muse, mutect2, varscan2
- MUC16 | c.7783A>T p.S2595C | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as COSV67468414; called by muse, mutect2, varscan2
- MYPOP | c.455A>T p.Q152L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV59133807; called by muse, mutect2, varscan2
- NFE2 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV56455969; called by muse, mutect2, varscan2
- NMBR | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV57801318; called by muse, varscan2
- NOVA2 | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54357445; called by muse, mutect2, varscan2
- NPAS3 | c.2098G>T p.G700W (on ENST00000356141 / NM_001164749.2; = p.G668W on NM_022123.3) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); catalogued as COSV60836001; called by muse, mutect2, varscan2
- NWD1 | c.2731+1G>C p.X911_splice | Splice Site (SNP) | VAF 4/11 reads (36%) | catalogued as COSV60343034; called by muse, mutect2, varscan2
- OLFML1 | c.714A>C p.K238N | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55077341; called by muse, mutect2, varscan2
- OR8J1 | c.146C>A p.T49N | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV57316671; called by muse, mutect2, varscan2
- PARD3 | c.3427A>G p.S1143G | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as rs1351712813, COSV61057155; called by muse, mutect2, varscan2
- PCDH15 | c.4610C>A p.S1537* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV57315784; called by muse, mutect2, varscan2
- PJA2 | c.917A>G p.H306R | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs865837752, COSV63272965; called by muse, mutect2, varscan2
- PNISR | c.761A>G p.E254G | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV65078690, COSV65079545; called by muse, mutect2
- PSAT1 | c.718T>C p.Y240H | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as COSV61302722; called by muse, mutect2, varscan2
- RAPGEF2 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 50/67 reads (75%) | catalogued as COSV52428515; called by muse, mutect2, varscan2
- RASGRP1 | c.1482A>C p.E494D | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.79); PolyPhen benign (0.317); catalogued as COSV60365283; called by muse, mutect2, varscan2
- RBBP6 | c.1992T>G p.D664E | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV60505289; called by muse, mutect2
- RBMXL2 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1364827695, COSV60980263; called by muse, mutect2, varscan2
- RCSD1 | c.533A>C p.Q178P | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV63258977; called by muse, mutect2
- RHOXF1 | c.445-1G>C p.X149_splice | Splice Site (SNP) | VAF 33/37 reads (89%) | catalogued as COSV54294691; called by muse, mutect2, varscan2
- RNF175 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV56841932; called by muse, mutect2, varscan2
- RYR3 | c.10526A>T p.H3509L (on ENST00000389232; = p.H3510L on NM_001036.6) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV66790625; called by muse, mutect2, varscan2
- SSTR4 | c.776G>A p.R259K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV54798201; called by muse, mutect2, varscan2
- SUFU | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV64014887; called by muse, mutect2, varscan2
- TBC1D25 | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV65123253, COSV65123784; called by muse, mutect2, varscan2
- TOGARAM2 | c.2526C>A p.H842Q | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV65421641; called by muse, mutect2, varscan2
- TRHR | c.223T>A p.L75M | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104411600, COSV61232979; called by muse, mutect2
- TRIM26 | c.1103T>A p.V368D | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV70983015; called by muse, mutect2, varscan2
- TRIM29 | c.823A>G p.K275E | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs1322019494; called by muse, mutect2
- TRIM58 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV63570355; called by muse, mutect2, varscan2
- TRPM3 | c.978A>T p.T326= (on ENST00000357533 / NM_001366142.2; = p.T171= on NM_020952.6) | Splice Region (SNP) | VAF 19/77 reads (25%) | catalogued as COSV62470447; called by muse, mutect2, varscan2
- TRPM3 | c.242C>G p.P81R (on ENST00000357533 / NM_001366142.2; = p.P50R on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV62468906, COSV62470470; called by muse, mutect2, varscan2
- TRRAP | c.5819A>T p.Q1940L (on ENST00000359863 / NM_001244580.1; = p.Q1922L on NM_003496.3) | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as COSV62844938; called by muse, mutect2, varscan2
- UBC | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.214); catalogued as COSV60059591; called by muse, varscan2
- USH2A | c.8717A>G p.N2906S | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56373729; called by muse, mutect2, varscan2
- VPS13C | c.8848G>A p.G2950R (on ENST00000644861 / NM_020821.3; = p.G2907R on NM_017684.5) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1390685383, COSV51187100; called by muse, mutect2, varscan2
- VPS8 | c.2679G>C p.E893D (on ENST00000625842 / NM_001349294.1; = p.E891D on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV54986348; called by muse, mutect2, varscan2
- WASHC3 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53532190; called by muse, mutect2, varscan2
- ZCCHC2 | c.2902C>G p.P968A | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54037944; called by muse, mutect2, varscan2
- ZMYM1 | c.1279A>G p.N427D | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV63251976; called by muse, mutect2, varscan2
- ZNF135 | c.1291A>G p.I431V (on ENST00000313434 / NM_001289401.2; = p.I443V on NM_003436.4) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.557); catalogued as COSV57882425; called by muse, mutect2
- ZNF518A | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60151509; called by muse, mutect2, varscan2
- ZNF777 | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56097760, COSV56100036; called by muse, mutect2, varscan2
- CALD1 | c.1992del p.K664Nfs*8 (on ENST00000361675 / NM_033138.4; = p.K409Nfs*8 on NM_004342.7) | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- PDE4DIP | c.342+1G>A p.X114_splice | Splice Site (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- RB1 | c.1446_1455delinsA p.F482_S485delinsL | In Frame Del (DEL) | VAF 39/54 reads (72%) | called by pindel, varscan2*
- RPS4Y1 | c.444_445dup p.Y149Sfs*9 | Frame Shift Ins (INS) | VAF 87/131 reads (66%) | called by mutect2, pindel, varscan2
- STX10 | c.320dup p.S108Qfs*12 | Frame Shift Ins (INS) | VAF 14/70 reads (20%) | called by mutect2, pindel, varscan2
- ZNF669 | c.933del p.C311Wfs*64 | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | called by mutect2, pindel, varscan2
- ZNF680 | c.260_261del p.Y87Ffs*5 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by pindel, varscan2
- ADAM29 | c.2193G>A p.Q731= | Silent (SNP) | VAF 49/57 reads (86%) | catalogued as COSV63661026, COSV63663870; called by muse, mutect2
- ADAMTS20 | c.1269A>G p.K423= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV67131926; called by muse, mutect2, varscan2
- AGER | c.1095G>A p.R365= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV61247691; called by muse, mutect2, varscan2
- ARMCX1 | c.810C>A p.A270= | Silent (SNP) | VAF 24/30 reads (80%) | catalogued as COSV100863151; called by muse, mutect2, varscan2
- BSG | c.549G>A p.L183= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1005985982, COSV61077023; called by muse, mutect2, varscan2
- CARD8 | c.612G>A p.E204= (on ENST00000651546 / NM_001184900.3; = p.E154= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 61/89 reads (69%) | catalogued as COSV62873578; called by muse, mutect2, varscan2
- CCNF | c.1395G>T p.G465= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV53540073; called by muse, mutect2, varscan2
- CD68 | c.27G>C p.G9= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs923135296, COSV51510888; called by muse, mutect2, varscan2
- CSMD3 | c.5793C>A p.S1931= (on ENST00000297405 / NM_001363185.1; = p.S1827= on NM_052900.3) | Silent (SNP) | VAF 82/212 reads (39%) | catalogued as COSV52188257, COSV52211153; called by muse, mutect2, varscan2
- CSTF2T | c.789A>T p.P263= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV58656514; called by muse, mutect2, varscan2
- CYP3A5 | c.303C>A p.V101= | Silent (SNP) | VAF 46/125 reads (37%) | catalogued as COSV56120107; called by muse, mutect2, varscan2
- DEPDC4 | c.69T>A p.L23= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV54553683; called by muse, mutect2, varscan2
- HPX | c.978A>G p.V326= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs377761910; called by muse, mutect2, varscan2
- IL12RB2 | c.1455T>C p.I485= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV52023612; called by muse, mutect2, varscan2
- IRF4 | c.51G>A p.V17= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as COSV66705216; called by muse, mutect2, varscan2
- KCNC3 | c.351G>A p.L117= | Silent (SNP) | VAF 4/8 reads (50%) | called by muse, varscan2
- MAP7 | c.606A>T p.S202= | Silent (SNP) | VAF 33/43 reads (77%) | catalogued as COSV63419959, COSV63423476; called by muse, mutect2, varscan2
- MFSD1 | c.426A>C p.G142= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV51840896; called by muse, mutect2, varscan2
- MN1 | c.381C>T p.C127= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV56558487; called by muse, mutect2, varscan2
- OR14I1 | c.813G>T p.V271= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV61199681; called by muse, mutect2, varscan2
- OR8G2P | c.261A>C p.T87= | Silent (SNP) | VAF 20/76 reads (26%) | called by muse, varscan2
- PCDHB1 | c.1956T>A p.A652= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV60631130; called by muse, mutect2, varscan2
- PRUNE2 | c.4419G>A p.E1473= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV65041846; called by muse, mutect2, varscan2
- SLC17A6 | c.471T>G p.A157= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV54136657; called by muse, mutect2, varscan2
- ST6GAL2 | c.1453C>T p.L485= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV62416729; called by muse, mutect2, varscan2
- CHRM2 | c.-47+33803G>A | Intron (SNP) | VAF 22/53 reads (42%) | catalogued as rs374751196; called by muse, mutect2, varscan2
- MAP2 | c.5074-2056A>T | Intron (SNP) | VAF 70/159 reads (44%) | catalogued as COSV52291917; called by muse, mutect2, varscan2
- MIR122 | n.11G>A | RNA (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
